CCDI case PBBRND — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/8f66c3c8-2e70-4ba7-8e81-02929e613df8

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Tumor cells, uncertain whether benign or malignant: ICD-O-3 morphology code: 8001/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,350 days).

Biospecimens (3 samples)
- Sample 0DFXF4: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DFXFC: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DFXH7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
